Gene-level copy-number profile of tumor specimen TCGA-CG-4462-01A from TCGA case TCGA-CG-4462, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 72.6 years (26,511 days).
Specimen TCGA-CG-4462-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.ef81126a-a607-4771-a6af-4b002ad7c6c1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-4462-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1bd1b51c-da36-4fa3-9db5-05677c3a24af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 594; copy number 2: 54,018; copy number 3: 5,041; copy number 4: 9; copy number 5: 21; copy number 6: 137.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-4462-01A-01D-1155-01): tumor purity 0.22, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 158 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:160,472,348–161,821,908, 21 genes, copy number 5: RNU7-136P, KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1.
- chr3:166,293,756–175,810,548, 137 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 493. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
